Somatic mutation profile of tumor specimen HCM-CSHL-0176-C25-01A (aliquot HCM-CSHL-0176-C25-01A-11D-A78L-36) from HCMI case HCM-CSHL-0176-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 60.0 years (21,917 days).
Specimen HCM-CSHL-0176-C25-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a832cdda-e3f0-457c-99ca-ca4c3d21df83.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0176-C25-10A (Blood Derived Normal), aliquot HCM-CSHL-0176-C25-10A-01D-A78L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/89f94ea0-76b0-4d2e-b3a8-b382958870ef

The open-access MAF lists 60 somatic variants for this specimen: 40 protein-altering or splice-affecting, 15 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, Silent 15, Nonsense Mutation 3, Intron 2, Frame Shift Ins 2, 5'Flank 1, 3'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 30/298 reads (10%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2
- TP53 | c.916C>T p.R306* | Nonsense Mutation (SNP) | VAF 67/466 reads (14%) | hotspot (GDC flag); catalogued as rs121913344, CM971506, COSV52662281, COSV52987117, COSV53852813; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AAR2 | c.580C>T p.R194W | Missense Mutation (SNP) | VAF 28/260 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs368104861; called by muse, mutect2, varscan2
- ADAMTSL3 | c.3350C>T p.A1117V | Missense Mutation (SNP) | VAF 16/130 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.086); catalogued as rs770183441, COSV54443001; called by muse, mutect2, varscan2
- ADGRD1 | c.2507C>T p.A836V | Missense Mutation (SNP) | VAF 31/253 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs367789023; called by muse, mutect2, varscan2
- ANK3 | c.3628C>T p.R1210W (on ENST00000280772 / NM_001320874.2; = p.R344W on NM_001149.3) | Missense Mutation (SNP) | VAF 33/305 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV55084035; called by muse, mutect2, varscan2
- CADM1 | c.1126G>A p.V376M | Missense Mutation (SNP) | VAF 65/444 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.965); catalogued as rs145171991; called by muse, mutect2, varscan2
- COL5A3 | c.2306C>T p.A769V | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs770509108, COSV53415167; called by muse, mutect2, varscan2
- DLGAP3 | c.1183G>A p.G395S | Missense Mutation (SNP) | VAF 50/359 reads (14%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.974); catalogued as rs140339373, COSV52395991, COSV52397212; called by muse, mutect2, varscan2
- DOCK11 | c.2819C>T p.T940M | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.411); catalogued as rs1051293197; called by muse, mutect2
- ELAVL1 | c.506G>C p.G169A | Missense Mutation (SNP) | VAF 31/258 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.781); catalogued as COSV60966159; called by muse, mutect2, varscan2
- G2E3 | c.271A>G p.I91V | Missense Mutation (SNP) | VAF 27/178 reads (15%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.994); catalogued as rs749078341; called by muse, mutect2, varscan2
- HRG | c.47C>T p.S16L | Missense Mutation (SNP) | VAF 42/237 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.715); catalogued as rs767043667, COSV99214688; called by muse, mutect2, varscan2
- IL4I1 | c.512G>A p.R171H | Missense Mutation (SNP) | VAF 59/573 reads (10%) | SIFT tolerated (0.34); PolyPhen benign (0.005); catalogued as rs776375305, COSV62010206; called by muse, mutect2
- KIF2B | c.1708G>A p.G570R | Missense Mutation (SNP) | VAF 18/179 reads (10%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs1159894082, COSV52126988; called by muse, mutect2, varscan2
- LHX9 | c.1072A>T p.T358S | Missense Mutation (SNP) | VAF 41/350 reads (12%) | SIFT tolerated (0.3); PolyPhen benign (0.018); catalogued as rs1557977692; called by muse, mutect2, varscan2
- MISP | c.730G>A p.V244M | Missense Mutation (SNP) | VAF 26/158 reads (16%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.706); catalogued as rs757717568; called by muse, mutect2, varscan2
- NCKAP5 | c.4110G>C p.L1370F | Missense Mutation (SNP) | VAF 25/166 reads (15%) | SIFT tolerated (0.57); PolyPhen benign (0.015); catalogued as COSV58436820; called by muse, mutect2, varscan2
- PAK6 | c.476C>T p.P159L | Missense Mutation (SNP) | VAF 16/154 reads (10%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs777888104; called by muse, mutect2, varscan2
- PLEC | c.13880G>A p.R4627H (on ENST00000322810 / NM_201380.4; = p.R4517H on NM_000445.5) | Missense Mutation (SNP) | VAF 54/370 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.959); catalogued as rs782151802; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLEKHM2 | c.2414A>G p.Y805C | Missense Mutation (SNP) | VAF 26/233 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs775550852; called by muse, mutect2, varscan2
- PTPRS | c.2786G>A p.R929H | Missense Mutation (SNP) | VAF 71/398 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.35); catalogued as rs1313647555, COSV53615144; called by muse, mutect2, varscan2
- SAMD9L | c.1877C>T p.S626L | Missense Mutation (SNP) | VAF 28/247 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.248); catalogued as rs1554341671, COSV59083752; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TPST1 | c.550C>T p.R184* | Nonsense Mutation (SNP) | VAF 35/315 reads (11%) | catalogued as rs779825014, COSV100507441; called by muse, mutect2, varscan2
- VDR | c.473G>A p.R158H | Missense Mutation (SNP) | VAF 35/228 reads (15%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.53); catalogued as rs1565613452; called by muse, mutect2, varscan2
- VWDE | c.4762A>G p.R1588G | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT tolerated (0.37); PolyPhen benign (0.037); catalogued as COSV51727970; called by muse, mutect2
- ZNF777 | c.1300G>A p.E434K | Missense Mutation (SNP) | VAF 20/162 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.251); catalogued as rs749320785, COSV56096567; called by muse, mutect2, varscan2
- CDX2 | c.104dup p.Q36Afs*192 | Frame Shift Ins (INS) | VAF 26/189 reads (14%) | called by mutect2, pindel, varscan2
- DCDC1 | c.620A>G p.N207S | Missense Mutation (SNP) | VAF 20/185 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- MAGIX | c.508G>A p.V170I | Missense Mutation (SNP) | VAF 20/182 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- MAP1A | c.2502G>C p.E834D | Missense Mutation (SNP) | VAF 61/346 reads (18%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.606); called by muse, mutect2, varscan2
- MAPRE2 | c.184G>A p.D62N | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); called by muse, mutect2
- RBM10 | c.1672C>T p.Q558* | Nonsense Mutation (SNP) | VAF 54/527 reads (10%) | called by muse, mutect2, varscan2
- REST | c.561dup p.V188Cfs*32 | Frame Shift Ins (INS) | VAF 20/134 reads (15%) | called by mutect2, pindel, varscan2
- SIGIRR | c.603C>G p.D201E | Missense Mutation (SNP) | VAF 25/178 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- SOWAHD | c.148G>A p.A50T | Missense Mutation (SNP) | VAF 24/197 reads (12%) | SIFT tolerated (0.37); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- YJU2 | c.722A>T p.K241M | Missense Mutation (SNP) | VAF 21/118 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); called by muse, mutect2, varscan2
- ZFC3H1 | c.122G>A p.S41N | Missense Mutation (SNP) | VAF 46/388 reads (12%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- ZNF219 | c.1983G>A p.M661I | Missense Mutation (SNP) | VAF 14/240 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.326); called by muse, mutect2
- ZNF570 | c.375G>C p.L125F | Missense Mutation (SNP) | VAF 27/245 reads (11%) | SIFT tolerated (0.93); PolyPhen possibly damaging (0.573); called by muse, mutect2, varscan2
- CNOT2 | c.1269G>A p.T423= | Silent (SNP) | VAF 22/209 reads (11%) | catalogued as COSV99972440; called by muse, mutect2, varscan2
- COL11A1 | c.2082G>T p.G694= | Silent (SNP) | VAF 51/417 reads (12%) | catalogued as COSV62184178; called by muse, mutect2, varscan2
- EGFLAM | c.2010C>T p.H670= | Silent (SNP) | VAF 65/209 reads (31%) | catalogued as rs199798525, COSV59292831; called by muse, mutect2, varscan2
- GRIN2A | c.684G>A p.L228= | Silent (SNP) | VAF 48/440 reads (11%) | called by muse, mutect2, varscan2
- KMT2A | c.1257G>A p.S419= | Silent (SNP) | VAF 10/68 reads (15%) | catalogued as rs141004205; called by muse, mutect2, varscan2
- MN1 | c.1158G>A p.A386= | Silent (SNP) | VAF 8/45 reads (18%) | catalogued as rs1259652005; called by muse, mutect2, varscan2
- MYH3 | c.483C>T p.N161= | Silent (SNP) | VAF 61/429 reads (14%) | catalogued as rs202066674; ClinVar: likely benign; called by muse, mutect2, varscan2
- MYOD1 | c.909C>T p.A303= | Silent (SNP) | VAF 13/103 reads (13%) | catalogued as rs545519590; called by muse, mutect2, varscan2
- NSDHL | c.1020C>T p.C340= | Silent (SNP) | VAF 45/310 reads (15%) | catalogued as rs376794048; ClinVar: likely benign; called by muse, mutect2, varscan2
- PCLO | c.1650G>A p.S550= | Silent (SNP) | VAF 110/483 reads (23%) | catalogued as rs780915122; called by muse, mutect2, varscan2
- SAGE1 | c.84G>A p.G28= | Silent (SNP) | VAF 26/212 reads (12%) | catalogued as rs1413402941; called by muse, mutect2, varscan2
- TNF | c.594G>A p.G198= | Silent (SNP) | VAF 21/179 reads (12%) | catalogued as rs751765776, COSV101403229; called by muse, mutect2, varscan2
- TSPEAR | c.1317G>A p.A439= | Silent (SNP) | VAF 20/118 reads (17%) | catalogued as rs782043381, COSV59973686; ClinVar: likely benign; called by muse, mutect2
- ZNF281 | c.1180T>C p.L394= | Silent (SNP) | VAF 20/232 reads (9%) | catalogued as rs1477938775; called by muse, mutect2
- ZNF687 | c.315C>T p.D105= | Silent (SNP) | VAF 33/273 reads (12%) | catalogued as rs202243324; called by muse, mutect2, varscan2
- ARHGEF4 | chr2:130916002 G>A | 5'Flank (SNP) | VAF 19/143 reads (13%) | catalogued as rs1160280833, COSV100388235; called by muse, mutect2, varscan2
- ATP2B2 | c.*350G>A | 3'UTR (SNP) | VAF 6/52 reads (12%) | catalogued as rs767698970; called by muse, mutect2
- ENO1 | c.1176+17C>T | Intron (SNP) | VAF 18/114 reads (16%) | called by muse, mutect2, varscan2
- MCF2L | c.3166-42C>T | Intron (SNP) | VAF 31/210 reads (15%) | catalogued as rs764138312; called by muse, mutect2, varscan2
- RBM8B | n.113G>A | RNA (SNP) | VAF 71/475 reads (15%) | catalogued as rs773963545; called by muse, mutect2, varscan2
